Gene-level copy-number profile of tumor specimen HCM-WCMC-0505-C16-01A from HCMI case HCM-WCMC-0505-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 75.9 years (27,705 days).
Specimen HCM-WCMC-0505-C16-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c2effb53-7a55-4dab-97e5-98b99aa5052b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0505-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,260 have no estimate.
https://portal.gdc.cancer.gov/files/3fc38095-3060-4e3c-9e76-460ca2b8239a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 41; copy number 2: 10,481; copy number 3: 28,100; copy number 4: 11,011; copy number 5: 3,543; copy number 6: 1,120; copy number 7: 2,256; copy number 8: 999; copy number 9: 191; copy number 10: 182; copy number 11: 114; copy number 12: 174; copy number 13: 32; copy number 14: 10; copy number 15: 49; copy number 17: 11; copy number 21: 1; copy number 32: 9; copy number 75: 18.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr8:7,836,436–7,868,867, 2 genes: DEFB104A, SPAG11A.
- chr8:12,087,396–12,177,550, 9 genes (within-gene range 0–3): RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr9:7,477,045–7,478,320, 1 gene: RPL4P5.
- chr11:4,242,056–4,279,192, 2 genes: SSU72P2, SSU72P6.
- chr16:32,600,299–32,622,184, 2 genes: AC137800.1, AC137800.2.
- chr21:8,680,538–8,680,934, 1 gene: CR381572.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,046 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,748,002–119,768,905, 1 gene, copy number 7: HMGCS2.
- chr1:143,419,625–182,336,334, 1,226 genes, copy number 7–9 (broad region; genes not listed).
- chr2:156,777,706–156,778,372, 1 gene, copy number 8: RPLP0P7.
- chr2:205,681,990–208,358,746, 84 genes, copy number 7–12 (broad region; genes not listed).
- chr5:138,331,935–138,575,675, 11 genes, copy number 12 (within-gene range 2–12): FAM53C, AC104116.1, KDM3B, REEP2, AC113403.1, EGR1, RPL7P19, ETF1, HSPA9, SNORD63B, SNORD63.
- chr6:34,696,317–34,773,857, 4 genes, copy number 9 (within-gene range 5–9): AL451165.2, AL451165.1, AL139100.1, SNRPC.
- chr6:56,431,950–56,433,213, 1 gene, copy number 7: RCC2P7.
- chr6:110,245,928–110,415,575, 3 genes, copy number 7 (within-gene range 4–7): METTL24, AL050350.1, DDO.
- chr7:66,485,095–68,724,048, 46 genes, copy number 7–9 (within-gene range 5–9): AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5, KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1, SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2, MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3, AC004910.1, RNA5SP231.
- chr7:70,837,738–93,148,385, 341 genes, copy number 7–75 (broad region; genes not listed).
- chr8:7,881,392–7,896,716, 3 genes, copy number 7: DEFB103A, HSPD1P2, DEFB4A.
- chr11:69,641,156–73,982,843, 152 genes, copy number 8–17 (within-gene range 8–22) (broad region; genes not listed).
- chr11:111,245,726–111,455,630, 7 genes, copy number 8 (within-gene range 4–8): C11orf53, COLCA1, COLCA2, MIR4491, POU2AF1, RNU2-60P, AP002008.3.
- chr12:14,169,746–14,255,226, 6 genes, copy number 10: AC092470.1, AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1.
- chr12:38,082,046–39,443,390, 19 genes, copy number 7 (within-gene range 4–7): CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A.
- chr15:88,459,477–88,656,483, 12 genes, copy number 7: MRPL46, AC013489.1, MRPS11, AC013489.3, DET1, AC013489.2, LINC01586, MIR1179, MIR7-2, MIR3529, AEN, ISG20.
- chr18:20,946,906–22,417,915, 39 genes, copy number 7: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1.
- chr18:23,134,564–23,260,467, 1 gene, copy number 8 (within-gene range 5–8): CABLES1.
- chr19:27,638,483–40,950,660, 501 genes, copy number 7–15 (broad region; genes not listed).
- chr19:43,951,223–45,602,212, 88 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr19:57,578,456–58,605,223, 94 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr20:87,250–64,327,972, 1,401 genes, copy number 7–10 (broad region; genes not listed).
- chr22:18,527,802–18,530,573, 1 gene, copy number 9: TMEM191B.
- chr22:18,615,581–18,615,900, 1 gene, copy number 21: Metazoa_SRP.
- chr22:18,636,445–18,719,341, 3 genes, copy number 8: CA15P2, PPP1R26P2, PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 41. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
